Somatic mutation profile of tumor specimen C3N-06054-02 (aliquot CPT0439170009) from CPTAC case C3N-06054, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 83.9 years (30,648 days).
Specimen C3N-06054-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 872f38d1-eea4-480a-9387-acd9a1d603ab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-06054-31 (Blood Derived Normal), aliquot CPT0444900005; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/04de1597-c604-4b77-af94-9a7edced142f

The open-access MAF lists 535 somatic variants for this specimen: 374 protein-altering or splice-affecting, 143 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 346, Silent 143, Nonsense Mutation 15, Intron 13, Splice Site 5, Splice Region 4, RNA 2, 3'UTR 2, Frame Shift Del 1, 5'Flank 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 344/572 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRAF | c.1918G>A p.V640M (on ENST00000288602 / NM_001374244.1; = p.V600M on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 341/570 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs121913378, COSV56066607, COSV56075762, COSV56124012, COSV56152883; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MYO7A | c.5968C>T p.Q1990* | Nonsense Mutation (SNP) | VAF 62/238 reads (26%) | catalogued as rs773844428, CM071020; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- VDR | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 38/228 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057521095, CM146690; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAM28 | c.2267C>T p.P756L | Missense Mutation (SNP) | VAF 41/249 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs370224864; called by muse, mutect2, varscan2
- ADAM29 | c.1975G>A p.G659R | Missense Mutation (SNP) | VAF 82/480 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63667711; called by muse, mutect2, varscan2
- ADAMTS12 | c.3346G>A p.E1116K | Missense Mutation (SNP) | VAF 95/571 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs371409097; called by muse, mutect2, varscan2
- ADCY4 | c.2314C>T p.R772C | Missense Mutation (SNP) | VAF 86/419 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.276); catalogued as rs147949610; called by muse, mutect2, varscan2
- ADGRB3 | c.911C>T p.S304L | Missense Mutation (SNP) | VAF 54/364 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773707304, COSV101000410, COSV65401204; called by muse, mutect2, varscan2
- AMBRA1 | c.2774C>T p.S925F (on ENST00000458649 / NM_001367468.1; = p.S835F on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 73/328 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV54055670; called by muse, mutect2, varscan2
- APOB | c.10899G>A p.W3633* | Nonsense Mutation (SNP) | VAF 84/485 reads (17%) | catalogued as COSV51938071; called by muse, mutect2, varscan2
- ARFGEF3 | c.2648G>A p.R883Q | Missense Mutation (SNP) | VAF 74/396 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.859); catalogued as rs747544365, COSV52450223; called by muse, mutect2, varscan2
- ATP5PB | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 96/523 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs751833359, COSV52384704; called by muse, mutect2, varscan2
- BMP10 | c.1011G>A p.W337* | Nonsense Mutation (SNP) | VAF 111/470 reads (24%) | catalogued as COSV54895204; called by muse, mutect2, varscan2
- BTK | c.1154C>T p.P385L | Missense Mutation (SNP) | VAF 98/261 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as CD961866; called by muse, mutect2, varscan2
- CA3 | c.677G>C p.R226P | Missense Mutation (SNP) | VAF 52/346 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs142979911, COSV53411632; called by muse, mutect2, varscan2
- CCDC81 | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 75/252 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as rs757152208; called by muse, mutect2, varscan2
- CD1C | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 88/612 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.034); catalogued as rs145638725, COSV63805710, COSV63806016; called by muse, mutect2, varscan2
- CDH26 | c.2104G>A p.E702K (on ENST00000348616 / NM_177980.4; = p.E35K on NM_021810.6) | Missense Mutation (SNP) | VAF 54/322 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758949641; called by muse, mutect2, varscan2
- CELF5 | c.614C>T p.S205F | Missense Mutation (SNP) | VAF 60/337 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.382); catalogued as COSV53011692; called by muse, mutect2, varscan2
- CFAP61 | c.2660C>T p.A887V | Missense Mutation (SNP) | VAF 101/539 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.039); catalogued as rs756237755; called by muse, mutect2, varscan2
- CHD9 | c.5476C>T p.P1826S | Missense Mutation (SNP) | VAF 56/361 reads (16%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.994); catalogued as rs756463231; called by muse, mutect2, varscan2
- CHL1 | c.1153G>A p.E385K (on ENST00000397491 / NM_001253387.1; = p.E401K on NM_006614.4) | Missense Mutation (SNP) | VAF 85/405 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV56610975; called by muse, mutect2, varscan2
- CLCN6 | c.2243C>T p.S748L | Missense Mutation (SNP) | VAF 102/480 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.123); catalogued as rs200061168, COSV56739958; called by muse, mutect2, varscan2
- CLCNKA | c.1739C>T p.P580L | Missense Mutation (SNP) | VAF 83/366 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58893634; called by muse, mutect2, varscan2
- CLEC2B | c.116G>A p.W39* | Nonsense Mutation (SNP) | VAF 52/280 reads (19%) | catalogued as rs1469693570; called by muse, mutect2, varscan2
- CLEC3A | c.508G>A p.G170S (on ENST00000651443; = p.G161S on NM_005752.6) | Missense Mutation (SNP) | VAF 76/463 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs762436240, COSV55223588; called by muse, mutect2, varscan2
- CNGB1 | c.1444G>A p.E482K | Missense Mutation (SNP) | VAF 101/487 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.292); catalogued as COSV99208867; called by muse, mutect2, varscan2
- COL14A1 | c.4553G>A p.G1518E | Missense Mutation (SNP) | VAF 50/297 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99920506; called by muse, mutect2, varscan2
- COL21A1 | c.2234G>A p.R745Q | Missense Mutation (SNP) | VAF 80/388 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as rs1554197993; called by muse, mutect2, varscan2
- COL3A1 | c.881G>A p.G294E | Missense Mutation (SNP) | VAF 37/213 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58594437; called by muse, mutect2, varscan2
- COL6A5 | c.5020G>A p.G1674R | Missense Mutation (SNP) | VAF 42/319 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773996405, COSV55193318; called by muse, varscan2
- COL7A1 | c.2332C>T p.R778C | Missense Mutation (SNP) | VAF 61/257 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.397); catalogued as rs1018322313, COSV60397842; called by muse, mutect2, varscan2
- CPSF1 | c.1172C>T p.S391F | Missense Mutation (SNP) | VAF 73/372 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV62939739; called by muse, varscan2
- CR2 | c.295G>A p.G99R | Missense Mutation (SNP) | VAF 70/539 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100889660, COSV65508724; called by muse, mutect2, varscan2
- CRYBG2 | c.4707G>A p.W1569* | Nonsense Mutation (SNP) | VAF 24/138 reads (17%) | catalogued as rs1292852085, COSV57483508; called by muse, mutect2, varscan2
- CSGALNACT1 | c.38C>T p.S13F | Missense Mutation (SNP) | VAF 89/393 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.459); catalogued as rs756334007; called by muse, mutect2, varscan2
- CSMD1 | c.10258G>A p.G3420S (on ENST00000520002; = p.G3419S on NM_033225.6) | Missense Mutation (SNP) | VAF 71/324 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.197); catalogued as rs753183110, COSV100152443; called by muse, mutect2, varscan2
- CSMD1 | c.2913G>A p.M971I (on ENST00000520002; = p.M970I on NM_033225.6) | Missense Mutation (SNP) | VAF 36/217 reads (17%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.921); catalogued as COSV59285935; called by muse, mutect2, varscan2
- CSMD3 | c.3643G>A p.E1215K (on ENST00000297405 / NM_001363185.1; = p.E1111K on NM_052900.3) | Missense Mutation (SNP) | VAF 75/402 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.588); catalogued as COSV52289954; called by muse, mutect2, varscan2
- CUL5 | c.910C>T p.P304S | Missense Mutation (SNP) | VAF 78/260 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs1288167795, COSV67609447; called by muse, mutect2, varscan2
- DCC | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 145/590 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59081081; called by muse, mutect2, varscan2
- DCLK2 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 45/327 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as COSV56198611; called by muse, mutect2, varscan2
- DDX60 | c.1682C>T p.S561L | Missense Mutation (SNP) | VAF 62/330 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV101190295; called by muse, mutect2, varscan2
- DGKG | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 79/439 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.184); catalogued as COSV53963398; called by muse, mutect2, varscan2
- DMP1 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 95/573 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.673); catalogued as rs914247002; called by muse, mutect2, varscan2
- DNAH3 | c.3826C>T p.H1276Y | Missense Mutation (SNP) | VAF 44/289 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV54527494; called by muse, mutect2, varscan2
- DNAH9 | c.5777G>A p.R1926Q | Missense Mutation (SNP) | VAF 80/382 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs866019340; called by muse, mutect2, varscan2
- DNER | c.1883C>G p.A628G | Missense Mutation (SNP) | VAF 61/304 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.823); catalogued as COSV100519750, COSV59163042; called by muse, mutect2, varscan2
- DNMT3A | c.2228C>T p.P743L | Missense Mutation (SNP) | VAF 95/485 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs755673156; called by muse, mutect2, varscan2
- EHD3 | c.1361C>T p.T454I | Missense Mutation (SNP) | VAF 88/542 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.366); catalogued as rs748099055; called by muse, mutect2, varscan2
- ENOX2 | c.1108C>T p.R370C (on ENST00000338144 / NM_001382520.1; = p.R341C on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs199818795, COSV57650385; called by muse, mutect2, varscan2
- EPPK1 | c.6892G>A p.E2298K | Missense Mutation (SNP) | VAF 26/594 reads (4%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.991); catalogued as COSV101599916; called by muse, mutect2
- ESM1 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 109/543 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101195661; called by muse, mutect2, varscan2
- FANCM | c.4271G>A p.R1424Q | Missense Mutation (SNP) | VAF 27/262 reads (10%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs1393856350, COSV57499649; called by muse, mutect2, varscan2
- FBXO34 | c.1358C>T p.S453F | Missense Mutation (SNP) | VAF 88/511 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.38); catalogued as COSV100571880, COSV100571944; called by muse, mutect2
- FHAD1 | c.2161C>T p.Q721* | Nonsense Mutation (SNP) | VAF 51/264 reads (19%) | catalogued as COSV100119671; called by muse, mutect2, varscan2
- FLT3LG | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 99/515 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs141645940; called by muse, mutect2, varscan2
- FOXK1 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 93/401 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV61065108; called by muse, mutect2, varscan2
- FSIP2 | c.19844C>T p.S6615L | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749127425; called by muse, mutect2, varscan2
- GAREM1 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 46/256 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as rs867423251; called by muse, mutect2, varscan2
- GLI2 | c.4069C>T p.P1357S (on ENST00000361492 / NM_001374353.1; = p.P1374S on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 100/564 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58040139; called by muse, mutect2, varscan2
- GPR88 | c.329G>A p.G110D | Missense Mutation (SNP) | VAF 103/433 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.395); catalogued as rs1420722195, COSV99043308; called by muse, mutect2, varscan2
- GRIA2 | c.1838C>T p.S613L | Missense Mutation (SNP) | VAF 37/196 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.058); catalogued as COSV52381735; called by muse, mutect2, varscan2
- GRIN3A | c.2209C>T p.P737S | Missense Mutation (SNP) | VAF 108/557 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866467593; called by muse, mutect2, varscan2
- GRM8 | c.1905C>G p.I635M | Missense Mutation (SNP) | VAF 203/807 reads (25%) | SIFT tolerated (0.9); PolyPhen benign (0.062); catalogued as COSV58820365; called by muse, mutect2, varscan2
- HMGCLL1 | c.994G>A p.G332S | Missense Mutation (SNP) | VAF 62/278 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51446126; called by muse, mutect2, varscan2
- HSD17B3 | c.214G>A p.G72R | Missense Mutation (SNP) | VAF 67/340 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100931242; called by muse, mutect2, varscan2
- IDO1 | c.737G>A p.G246D | Missense Mutation (SNP) | VAF 85/422 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768228145; called by muse, mutect2, varscan2
- IFT46 | c.791C>T p.S264F (on ENST00000264021 / NM_001168618.2; = p.S315F on NM_020153.3) | Missense Mutation (SNP) | VAF 53/243 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs541692586; called by muse, mutect2, varscan2
- IGKV3-11 | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 47/249 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs2848074; called by muse, mutect2, varscan2
- IL2RA | c.556G>A p.G186S | Missense Mutation (SNP) | VAF 70/242 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1221215026; called by muse, mutect2, varscan2
- IMPG2 | c.1774G>A p.E592K | Missense Mutation (SNP) | VAF 69/322 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.563); catalogued as COSV51983330; called by muse, mutect2, varscan2
- INTS1 | c.5920G>A p.A1974T | Missense Mutation (SNP) | VAF 67/313 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1246574973; called by muse, mutect2, varscan2
- ITGAD | c.2911C>T p.P971S | Missense Mutation (SNP) | VAF 78/351 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104381394; called by muse, mutect2, varscan2
- KCNV1 | c.554C>T p.S185F | Missense Mutation (SNP) | VAF 94/475 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV52089077; called by muse, mutect2, varscan2
- KCTD8 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 55/276 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.023); catalogued as rs1560385987, COSV100759700; called by muse, mutect2, varscan2
- KIAA0232 | c.2402A>G p.E801G | Missense Mutation (SNP) | VAF 55/330 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.526); catalogued as rs1268824260, COSV99072804; called by muse, mutect2, varscan2
- KIF26B | c.4799C>T p.P1600L | Missense Mutation (SNP) | VAF 154/922 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1349961054; called by muse, mutect2, varscan2
- KL | c.2197G>A p.D733N | Missense Mutation (SNP) | VAF 16/372 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); catalogued as COSV101199232, COSV66308147; called by muse, mutect2
- KRT72 | c.723G>A p.M241I | Missense Mutation (SNP) | VAF 71/335 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.232); catalogued as rs774770393, COSV53374338; called by muse, mutect2, varscan2
- L3MBTL4 | c.1252C>T p.H418Y | Missense Mutation (SNP) | VAF 177/472 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.162); catalogued as rs1182014805; called by muse, mutect2, varscan2
- LRP2 | c.4495G>A p.D1499N | Missense Mutation (SNP) | VAF 58/274 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV55569755, COSV99787150; called by muse, mutect2, varscan2
- LTF | c.1588G>A p.E530K | Missense Mutation (SNP) | VAF 94/497 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.155); catalogued as rs541413302, COSV51610172; called by muse, mutect2, varscan2
- MAST4 | c.5023C>T p.R1675* (on ENST00000403625 / NM_001164664.2; = p.R1486* on NM_015183.3) | Nonsense Mutation (SNP) | VAF 118/494 reads (24%) | catalogued as rs1359248845, COSV55131533; called by muse, mutect2, varscan2
- MEGF6 | c.449C>T p.P150L | Missense Mutation (SNP) | VAF 95/426 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as rs1167156268; called by muse, mutect2, varscan2
- MISP | c.503G>A p.G168E | Missense Mutation (SNP) | VAF 118/501 reads (24%) | SIFT tolerated (0.89); PolyPhen benign (0.102); catalogued as COSV53118921; called by muse, mutect2, varscan2
- MKRN3 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 88/450 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV58809475; called by muse, mutect2, varscan2
- MMP9 | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 58/272 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.605); catalogued as rs200848405, COSV63433757; called by muse, mutect2, varscan2
- MPIG6B | c.580G>A p.E194K (on ENST00000649779 / NM_138272.3; = p.G200E on NM_025260.4) | Missense Mutation (SNP) | VAF 114/647 reads (18%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as COSV65389405; called by muse, mutect2, varscan2
- MPP2 | c.923C>T p.P308L (on ENST00000461854 / NM_001278372.2; = p.P284L on NM_005374.5) | Missense Mutation (SNP) | VAF 94/365 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52240966; called by muse, mutect2, varscan2
- MTUS2 | c.1841G>A p.G614E | Missense Mutation (SNP) | VAF 14/444 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as COSV70916623; called by muse, mutect2
- MYH8 | c.5581C>T p.R1861C | Missense Mutation (SNP) | VAF 52/310 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as rs760517620; called by muse, mutect2, varscan2
- MYOZ2 | c.145C>T p.H49Y | Missense Mutation (SNP) | VAF 88/516 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.173); catalogued as COSV61086477; called by muse, mutect2, varscan2
- NBEAL2 | c.1012C>T p.R338W | Missense Mutation (SNP) | VAF 42/287 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as rs751200449, COSV99437457; called by muse, mutect2, varscan2
- NEB | c.10987C>T p.R3663C | Missense Mutation (SNP) | VAF 64/384 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759419548, COSV50913182; called by muse, mutect2, varscan2
- NEFL | c.1262G>A p.R421Q | Missense Mutation (SNP) | VAF 109/489 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.905); catalogued as rs1463847045, COSV99648004; called by muse, mutect2, varscan2
- NFXL1 | c.1189C>T p.P397S | Missense Mutation (SNP) | VAF 73/360 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.801); catalogued as rs1234958730, COSV61198956; called by muse, mutect2, varscan2
- NLRP13 | c.1748C>T p.P583L | Missense Mutation (SNP) | VAF 93/479 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1196761459; called by muse, mutect2, varscan2
- NSUN7 | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 85/367 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773389446, COSV57274610; called by muse, mutect2, varscan2
- OR2A2 | c.725C>T p.S242F | Missense Mutation (SNP) | VAF 409/822 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101286694; called by muse, mutect2, varscan2
- OR2T8 | c.34C>T p.L12F | Missense Mutation (SNP) | VAF 73/452 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.162); catalogued as rs375773183, COSV60664701; called by muse, varscan2
- OR2V1 | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 99/448 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.06); catalogued as rs1429437974, COSV61459639; called by muse, mutect2, varscan2
- OR5AC2 | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 108/507 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.176); catalogued as rs372644364, COSV62279508; called by muse, mutect2, varscan2
- OSBPL6 | c.2329G>A p.E777K | Missense Mutation (SNP) | VAF 72/376 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.299); catalogued as COSV51912717; called by muse, mutect2, varscan2
- OTOL1 | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 53/337 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV60008229; called by muse, mutect2, varscan2
- P4HA3 | c.608G>A p.W203* | Nonsense Mutation (SNP) | VAF 50/262 reads (19%) | catalogued as rs746343605; called by muse, mutect2, varscan2
- PBRM1 | c.862G>T p.E288* | Nonsense Mutation (SNP) | VAF 30/161 reads (19%) | catalogued as COSV56269824; called by muse, mutect2, varscan2
- PCDH10 | c.2993G>A p.R998Q | Missense Mutation (SNP) | VAF 86/483 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs140421804; called by muse, mutect2, varscan2
- PCDHA1 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 65/269 reads (24%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.197); catalogued as rs143010606, COSV65373538; called by muse, mutect2, varscan2
- PCLO | c.9721G>A p.E3241K | Missense Mutation (SNP) | VAF 83/524 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV100427701; called by muse, mutect2, varscan2
- PDE8B | c.1107G>A p.G369= | Splice Region (SNP) | VAF 38/232 reads (16%) | catalogued as COSV99366423; called by muse, mutect2, varscan2
- PELP1 | c.947C>T p.S316L | Missense Mutation (SNP) | VAF 72/348 reads (21%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.524); catalogued as rs748407658, COSV52592274; called by muse, mutect2, varscan2
- PEX5L | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 39/284 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as rs374485695; called by muse, mutect2, varscan2
- PGAP6 | c.1184A>C p.D395A | Missense Mutation (SNP) | VAF 31/452 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as COSV51739177; called by muse, mutect2
- PHF12 | c.1489C>T p.P497S | Missense Mutation (SNP) | VAF 86/474 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV52021912; called by muse, mutect2, varscan2
- PHLDB2 | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 98/435 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as COSV67315145; called by muse, mutect2, varscan2
- PKN3 | c.2654G>A p.R885Q | Missense Mutation (SNP) | VAF 69/364 reads (19%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.007); catalogued as rs574891762, COSV52580096; called by muse, mutect2, varscan2
- PLA2G3 | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 96/548 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.166); catalogued as rs957019241, COSV53207886; called by muse, mutect2, varscan2
- PLXDC1 | c.116G>A p.G39E | Missense Mutation (SNP) | VAF 71/436 reads (16%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs1326690224; called by muse, mutect2, varscan2
- PLXNA4 | c.2656G>A p.E886K | Missense Mutation (SNP) | VAF 147/1016 reads (14%) | SIFT tolerated (0.88); PolyPhen benign (0.01); catalogued as COSV58122433; called by muse, mutect2, varscan2
- PLXNA4 | c.2317G>C p.E773Q | Missense Mutation (SNP) | VAF 130/779 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.196); catalogued as COSV58150220, COSV58155233; called by muse, mutect2, varscan2
- POLE3 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 66/351 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0.021); catalogued as rs1446093192; called by muse, mutect2, varscan2
- POM121C | c.3665G>A p.R1222Q (on ENST00000607367; = p.R980Q on NM_001099415.3) | Missense Mutation (SNP) | VAF 19/592 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1286719514, COSV57547274; called by muse, mutect2
- POM121L2 | c.2861C>T p.S954F | Missense Mutation (SNP) | VAF 113/486 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV66277542; called by muse, mutect2, varscan2
- PPP1R18 | c.1322C>T p.P441L | Missense Mutation (SNP) | VAF 100/442 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs749914386; called by muse, mutect2, varscan2
- PPP1R3A | c.2764G>A p.E922K | Missense Mutation (SNP) | VAF 64/573 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs868268486, COSV52879587; called by muse, mutect2, varscan2
- PPP4R4 | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 83/379 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58553213; called by muse, mutect2, varscan2
- PRR12 | c.3239C>T p.S1080L (on ENST00000615927; = p.S1901L on NM_020719.3) | Missense Mutation (SNP) | VAF 87/391 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as COSV69816604; called by muse, mutect2, varscan2
- PRSS57 | c.698C>T p.S233F | Missense Mutation (SNP) | VAF 80/486 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51262030; called by muse, mutect2, varscan2
- PXDNL | c.1444G>A p.D482N | Missense Mutation (SNP) | VAF 120/486 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.902); catalogued as rs757058225, COSV62485102; called by muse, mutect2, varscan2
- RAB3A | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 68/366 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs961892301, COSV55852284; called by muse, mutect2, varscan2
- RBBP6 | c.1204C>T p.P402S | Missense Mutation (SNP) | VAF 97/439 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV60502948; called by muse, mutect2, varscan2
- RCSD1 | c.329G>A p.G110E | Missense Mutation (SNP) | VAF 87/665 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs1297432343; called by muse, mutect2, varscan2
- RP1 | c.1292C>T p.S431L | Missense Mutation (SNP) | VAF 50/262 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs976078408; called by muse, mutect2, varscan2
- SAGE1 | c.1576G>A p.D526N | Missense Mutation (SNP) | VAF 52/141 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.948); catalogued as COSV61015744; called by muse, mutect2, varscan2
- SCAF1 | c.2009C>T p.S670F | Missense Mutation (SNP) | VAF 104/507 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.056); catalogued as rs775496705; called by muse, varscan2
- SCN9A | c.5240C>T p.S1747F (on ENST00000303354; = p.S1736F on NM_002977.3) | Missense Mutation (SNP) | VAF 51/333 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57603337, COSV57623031; called by muse, mutect2, varscan2
- SDK1 | c.4615G>A p.V1539I | Missense Mutation (SNP) | VAF 56/294 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as rs374321407; called by mutect2, varscan2
- SEMA6B | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 105/429 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0.044); catalogued as rs564318828; called by muse, mutect2, varscan2
- SERPINA3 | c.1034G>A p.G345E | Missense Mutation (SNP) | VAF 65/390 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs758030744, COSV67586379; called by muse, mutect2, varscan2
- SERPINA4 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 80/403 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.015); catalogued as rs1243854935; called by muse, mutect2, varscan2
- SFXN1 | c.625G>A p.D209N | Missense Mutation (SNP) | VAF 53/253 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.33); catalogued as rs1361076036; called by muse, mutect2, varscan2
- SIGLEC12 | c.758G>A p.G253E (on ENST00000291707 / NM_053003.4; = p.G135E on NM_033329.2) | Missense Mutation (SNP) | VAF 94/437 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV52460753; called by muse, mutect2, varscan2
- SIX5 | c.884C>T p.S295F | Missense Mutation (SNP) | VAF 123/651 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as rs1221627931, COSV52175669; called by muse, mutect2, varscan2
- SLC12A3 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 74/386 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148945966, CM075012, COSV99344049; called by muse, varscan2
- SLC26A7 | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 29/163 reads (18%) | SIFT tolerated (0.73); PolyPhen benign (0.239); catalogued as COSV52592753; called by muse, mutect2, varscan2
- SLC38A1 | c.88G>A p.D30N | Missense Mutation (SNP) | VAF 52/292 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV67063585; called by muse, mutect2, varscan2
- SLC39A9 | c.853C>T p.R285C | Missense Mutation (SNP) | VAF 80/413 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as rs17855898, COSV50362019; called by muse, mutect2, varscan2
- SLC8A1 | c.1955G>A p.G652E | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT tolerated (0.83); PolyPhen benign (0.207); catalogued as rs1188117057, COSV60493639; called by muse, mutect2, varscan2
- SORL1 | c.2275G>A p.E759K | Missense Mutation (SNP) | VAF 51/206 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as rs1272070582; called by muse, mutect2, varscan2
- SRC | c.482C>T p.S161L | Missense Mutation (SNP) | VAF 76/338 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as COSV100658297; called by muse, mutect2, varscan2
- STARD8 | c.1438G>A p.D480N | Missense Mutation (SNP) | VAF 123/300 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV52927257; called by muse, mutect2, varscan2
- SVEP1 | c.1565G>A p.G522E | Missense Mutation (SNP) | VAF 98/491 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868299304, COSV100237591; called by muse, mutect2, varscan2
- SYNJ2 | c.3295C>T p.P1099S | Missense Mutation (SNP) | VAF 96/472 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs761657265; called by muse, mutect2
- TBC1D1 | c.3208G>A p.D1070N | Missense Mutation (SNP) | VAF 74/412 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.322); catalogued as rs770144771, COSV54722829; called by muse, mutect2, varscan2
- TEK | c.479C>T p.S160F | Missense Mutation (SNP) | VAF 41/218 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as COSV66228027; called by muse, mutect2, varscan2
- TMC1 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 54/335 reads (16%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.885); catalogued as rs753977925, COSV52787145; called by muse, mutect2, varscan2
- TMEM132C | c.1733C>T p.T578I | Missense Mutation (SNP) | VAF 88/576 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.167); catalogued as rs868215319; called by muse, mutect2, varscan2
- TMEM185A | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 43/213 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.078); catalogued as rs1449637278; called by muse, mutect2, varscan2
- TMEM92 | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 102/496 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs1466275959; called by muse, mutect2, varscan2
- TMPRSS15 | c.1871G>A p.R624K | Missense Mutation (SNP) | VAF 71/439 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV53043976; called by muse, mutect2, varscan2
- TNXB | c.7532G>A p.G2511D (on ENST00000647633; = p.G2264D on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 89/465 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64473033; called by muse, mutect2, varscan2
- TRBV28 | c.80C>T p.S27L | Missense Mutation (SNP) | VAF 114/298 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs745393218; called by muse, mutect2, varscan2
- TTBK1 | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 73/418 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs150345154; called by muse, mutect2, varscan2
- TYK2 | c.1253C>T p.S418L | Missense Mutation (SNP) | VAF 105/456 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as rs759111483; called by muse, mutect2, varscan2
- UGT2B28 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 33/211 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.17); catalogued as COSV100158914, COSV59433651; called by muse, mutect2, varscan2
- UQCRC1 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 49/243 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.423); catalogued as rs1461074745; called by muse, mutect2, varscan2
- USH2A | c.5002G>A p.G1668S | Missense Mutation (SNP) | VAF 134/368 reads (36%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.979); catalogued as rs1487579070, COSV100244201; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WASF3 | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 62/273 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100099130; called by muse, mutect2, varscan2
- ZBED9 | c.2965G>A p.E989K | Missense Mutation (SNP) | VAF 101/544 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.023); catalogued as rs867739512, COSV71729300; called by muse, mutect2, varscan2
- ZC3H4 | c.767C>T p.S256L | Missense Mutation (SNP) | VAF 106/648 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as rs368184376, COSV53416489; called by muse, mutect2, varscan2
- ZFHX3 | c.1837G>A p.D613N | Missense Mutation (SNP) | VAF 127/562 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as rs761739295, COSV51714516; called by muse, mutect2, varscan2
- ZFHX4 | c.9805G>A p.G3269R | Missense Mutation (SNP) | VAF 68/426 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51496052; called by muse, mutect2, varscan2
- ZNF831 | c.4178G>A p.R1393Q | Missense Mutation (SNP) | VAF 49/261 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as rs753837433, COSV64037136; called by muse, mutect2, varscan2
- ZNF98 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 62/390 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.013); catalogued as COSV63334101; called by muse, varscan2
- AACS | c.551C>T p.S184F | Missense Mutation (SNP) | VAF 83/391 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- AATK | c.2108G>A p.G703D (on ENST00000326724 / NM_001080395.3; = p.G600D on NM_004920.2) | Missense Mutation (SNP) | VAF 137/621 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ABCC12 | c.2415G>A p.M805I | Missense Mutation (SNP) | VAF 115/474 reads (24%) | SIFT tolerated (0.61); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ABI3BP | c.1022C>T p.P341L | Missense Mutation (SNP) | VAF 50/306 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- AC099489.1 | c.2113G>A p.E705K | Missense Mutation (SNP) | VAF 85/404 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADCY5 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 41/181 reads (23%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AFDN | c.5417A>T p.N1806I (on ENST00000447894 / NM_001366320.1; = p.N1725I on NM_001207008.1) | Missense Mutation (SNP) | VAF 52/408 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- AL035461.3 | c.2926A>C p.I976L | Missense Mutation (SNP) | VAF 37/321 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- AL645922.1 | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 133/604 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- ALPG | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 119/578 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ANAPC5 | c.847C>T p.L283F | Missense Mutation (SNP) | VAF 63/387 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- APC2 | c.5675dup p.V1893Gfs*260 | Frame Shift Ins (INS) | VAF 90/544 reads (17%) | called by mutect2, pindel, varscan2
- ATG7 | c.1673C>T p.A558V | Missense Mutation (SNP) | VAF 54/272 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ATRN | c.4216G>A p.V1406M | Missense Mutation (SNP) | VAF 49/376 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- ATRN | c.4217T>A p.V1406E | Missense Mutation (SNP) | VAF 49/379 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BCL11B | c.882G>C p.M294I (on ENST00000357195 / NM_001282237.2; = p.M223I on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 130/633 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- BPTF | c.5813C>T p.S1938F | Missense Mutation (SNP) | VAF 38/230 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- C19orf85 | c.634G>A p.G212R | Missense Mutation (SNP) | VAF 71/384 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CACNA1A | c.1774A>G p.K592E | Missense Mutation (SNP) | VAF 51/230 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CAPS2 | c.769G>A p.D257N | Missense Mutation (SNP) | VAF 59/311 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- CCDC110 | c.1370C>T p.S457F | Missense Mutation (SNP) | VAF 66/309 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- CCDC191 | c.1310T>C p.L437P | Missense Mutation (SNP) | VAF 96/490 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC39 | c.1154A>G p.E385G | Missense Mutation (SNP) | VAF 59/241 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCT6B | c.922C>G p.H308D | Missense Mutation (SNP) | VAF 48/250 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CCT8L2 | c.1303G>A p.G435R | Missense Mutation (SNP) | VAF 77/409 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- CD163 | c.2969C>A p.P990Q | Missense Mutation (SNP) | VAF 72/391 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- CD163 | c.1570G>A p.V524I | Missense Mutation (SNP) | VAF 82/422 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- CD99 | c.257C>T p.S86F | Missense Mutation (SNP) | VAF 117/424 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- CDK14 | c.1261G>C p.D421H (on ENST00000380050 / NM_001287135.2; = p.D403H on NM_012395.3) | Missense Mutation (SNP) | VAF 52/514 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.406); called by muse, mutect2
- CELSR2 | c.7505C>T p.P2502L | Missense Mutation (SNP) | VAF 51/372 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CENPI | c.1241_1242insGGT p.F414delinsLV | In Frame Ins (INS) | VAF 39/128 reads (30%) | called by mutect2, pindel, varscan2
- CFAP46 | c.7936G>A p.A2646T | Missense Mutation (SNP) | VAF 101/410 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- CFAP54 | c.1864C>T p.Q622* | Nonsense Mutation (SNP) | VAF 68/383 reads (18%) | called by muse, mutect2, varscan2
- CHST12 | c.622C>T p.H208Y | Missense Mutation (SNP) | VAF 140/614 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL20A1 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 69/326 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- COL22A1 | c.342C>G p.N114K | Missense Mutation (SNP) | VAF 133/574 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- CPAMD8 | c.2980C>T p.P994S (on ENST00000651564; = p.P947S on NM_015692.5) | Missense Mutation (SNP) | VAF 92/437 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CR1 | c.5701G>A p.D1901N | Missense Mutation (SNP) | VAF 50/381 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- CRAMP1 | c.2452C>T p.P818S | Missense Mutation (SNP) | VAF 67/294 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- CRYM | c.679G>A p.G227R | Missense Mutation (SNP) | VAF 50/223 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CTSG | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 63/355 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CUL5 | c.383C>A p.S128* | Nonsense Mutation (SNP) | VAF 34/222 reads (15%) | called by muse, mutect2, varscan2
- CUX2 | c.613G>T p.E205* | Nonsense Mutation (SNP) | VAF 67/362 reads (19%) | called by muse, mutect2, varscan2
- CYP2C19 | c.887G>A p.G296E | Missense Mutation (SNP) | VAF 62/345 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- DBX1 | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 81/360 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- DHX37 | c.2237C>T p.A746V | Missense Mutation (SNP) | VAF 71/398 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- DKK2 | c.671G>A p.G224E | Missense Mutation (SNP) | VAF 78/377 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DKK2 | c.670G>A p.G224R | Missense Mutation (SNP) | VAF 80/383 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAH14 | c.293A>G p.D98G | Missense Mutation (SNP) | VAF 116/768 reads (15%) | called by muse, mutect2, varscan2
- DNAH14 | c.9670G>A p.G3224R (on ENST00000445597; = p.G4232R on NM_001367479.1) | Missense Mutation (SNP) | VAF 62/496 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH2 | c.9817G>A p.E3273K | Missense Mutation (SNP) | VAF 92/490 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- EFCAB5 | c.2083G>A p.V695I | Missense Mutation (SNP) | VAF 74/371 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ENPP4 | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 29/187 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- EPB41L2 | c.1538C>T p.S513F | Missense Mutation (SNP) | VAF 69/403 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPHA8 | c.2801C>T p.T934I | Missense Mutation (SNP) | VAF 134/606 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- ERICH5 | c.438T>G p.N146K | Missense Mutation (SNP) | VAF 101/465 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- EXOC6 | c.1135C>T p.H379Y | Missense Mutation (SNP) | VAF 47/188 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- FAM170A | c.720G>A p.M240I | Missense Mutation (SNP) | VAF 112/525 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM200A | c.460C>T p.P154S | Missense Mutation (SNP) | VAF 357/651 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FAM20C | c.889C>T p.P297S | Missense Mutation (SNP) | VAF 54/319 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- FASN | c.3420_3427+10delinsA p.X1140_splice | Splice Site (DEL) | VAF 63/310 reads (20%) | called by pindel, varscan2*
- FAT3 | c.4119A>T p.E1373D | Missense Mutation (SNP) | VAF 62/291 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- FBXW11 | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 81/400 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FCRL3 | c.912T>A p.N304K | Missense Mutation (SNP) | VAF 264/624 reads (42%) | SIFT tolerated (0.64); PolyPhen benign (0.017); called by mutect2, varscan2
- FCRL5 | c.2358T>A p.F786L | Missense Mutation (SNP) | VAF 327/762 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- FGF2 | c.665G>T p.G222V | Missense Mutation (SNP) | VAF 78/351 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FILIP1L | c.1733G>A p.G578E (on ENST00000354552 / NM_182909.3; = p.G338E on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 79/350 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- FLT3 | c.539A>T p.D180V | Missense Mutation (SNP) | VAF 58/273 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.508); called by muse, mutect2, varscan2
- FRMD4A | c.22G>A p.D8N | Missense Mutation (SNP) | VAF 78/322 reads (24%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FSCB | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 90/480 reads (19%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- FSIP2 | c.7874C>T p.P2625L | Missense Mutation (SNP) | VAF 12/358 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2
- GOLGA6L2 | c.2012G>A p.G671E | Missense Mutation (SNP) | VAF 151/1147 reads (13%) | SIFT tolerated, low confidence (0.64); called by muse, mutect2, varscan2
- GOLGA8H | c.678G>A p.Q226= | Splice Region (SNP) | VAF 43/371 reads (12%) | called by muse, mutect2, varscan2
- GOLGB1 | c.5687T>G p.L1896R | Missense Mutation (SNP) | VAF 80/353 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- GRID1 | c.1322T>C p.V441A | Missense Mutation (SNP) | VAF 61/285 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- GRIK4 | c.1408G>A p.D470N | Missense Mutation (SNP) | VAF 16/382 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GRIN2C | c.1550C>T p.S517F | Missense Mutation (SNP) | VAF 80/358 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- GTPBP1 | c.397C>T p.L133F | Missense Mutation (SNP) | VAF 86/429 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.287); called by muse, varscan2
- GUCY1A2 | c.491T>C p.L164S | Missense Mutation (SNP) | VAF 43/170 reads (25%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- HCK | c.112T>A p.S38T | Missense Mutation (SNP) | VAF 79/377 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- HEATR9 | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 103/526 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HEG1 | c.2023C>T p.P675S | Missense Mutation (SNP) | VAF 115/509 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- HELZ2 | c.5756C>T p.P1919L (on ENST00000467148 / NM_001037335.2; = p.P1350L on NM_033405.3) | Missense Mutation (SNP) | VAF 97/444 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- HID1 | c.1535C>T p.A512V | Missense Mutation (SNP) | VAF 78/422 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- HMCN1 | c.11410C>T p.P3804S | Missense Mutation (SNP) | VAF 134/339 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HOXA2 | c.487C>T p.H163Y | Missense Mutation (SNP) | VAF 81/382 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HYDIN | c.10423C>T p.P3475S | Missense Mutation (SNP) | VAF 73/361 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IFNA2 | c.244A>T p.M82L | Missense Mutation (SNP) | VAF 63/352 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- IGDCC4 | c.1999G>A p.E667K | Missense Mutation (SNP) | VAF 114/551 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- IL13RA1 | c.279G>T p.R93S | Missense Mutation (SNP) | VAF 75/193 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- IL22RA1 | c.1113A>C p.E371D | Missense Mutation (SNP) | VAF 131/710 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IMPDH2 | c.1498G>A p.E500K | Missense Mutation (SNP) | VAF 90/426 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- IPO8 | c.959C>T p.P320L | Missense Mutation (SNP) | VAF 71/425 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ITGA11 | c.211G>A p.G71R | Missense Mutation (SNP) | VAF 67/409 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNU1 | c.1520T>G p.V507G | Missense Mutation (SNP) | VAF 40/248 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- KIAA2012 | c.2811G>A p.K937= | Splice Region (SNP) | VAF 44/233 reads (19%) | called by muse, mutect2, varscan2
- KLHDC7B | c.655G>A p.D219N (on ENST00000395676; = p.D860N on NM_138433.5) | Missense Mutation (SNP) | VAF 448/934 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- LINC02218 | c.170G>A p.G57D | Missense Mutation (SNP) | VAF 142/432 reads (33%) | SIFT tolerated (0.62); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- LRMDA | c.563A>T p.E188V | Missense Mutation (SNP) | VAF 96/325 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRN3 | c.1058C>T p.T353I | Missense Mutation (SNP) | VAF 291/658 reads (44%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MAGEL2 | c.1199C>T p.A400V | Missense Mutation (SNP) | VAF 135/667 reads (20%) | SIFT tolerated, low confidence (0.52); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- MAN2C1 | c.895C>T p.Q299* | Nonsense Mutation (SNP) | VAF 42/262 reads (16%) | called by muse, mutect2, varscan2
- MAP3K5 | c.2345T>C p.F782S | Missense Mutation (SNP) | VAF 58/313 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MARCHF11 | c.1160C>T p.S387L | Missense Mutation (SNP) | VAF 77/458 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- MBOAT4 | c.24T>A p.F8L | Missense Mutation (SNP) | VAF 59/320 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- MREG | c.586G>A p.V196I | Missense Mutation (SNP) | VAF 85/352 reads (24%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MRGPRE | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 134/484 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- MTMR10 | c.788C>T p.S263F | Missense Mutation (SNP) | VAF 69/367 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- MXRA5 | c.8414C>T p.A2805V | Missense Mutation (SNP) | VAF 98/272 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MYL1 | c.434G>A p.G145D | Missense Mutation (SNP) | VAF 86/390 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MYO15A | c.2975G>A p.R992K | Missense Mutation (SNP) | VAF 103/542 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYRFL | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 44/314 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- MYRFL | c.2443G>A p.E815K | Missense Mutation (SNP) | VAF 50/276 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NOS1 | c.4124G>A p.G1375E | Missense Mutation (SNP) | VAF 77/419 reads (18%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NPR1 | c.1232G>A p.W411* | Nonsense Mutation (SNP) | VAF 249/571 reads (44%) | called by muse, mutect2, varscan2
- NSD1 | c.3299A>G p.E1100G | Missense Mutation (SNP) | VAF 81/365 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- OBSCN | c.10360G>A p.E3454K | Missense Mutation (SNP) | VAF 133/305 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- OBSCN | c.19720G>A p.G6574R | Missense Mutation (SNP) | VAF 195/486 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- OR2AP1 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 67/326 reads (21%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- OR2B2 | c.88A>G p.M30V | Missense Mutation (SNP) | VAF 69/440 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- OR2F1 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 139/715 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR2Y1 | c.713G>A p.G238E | Missense Mutation (SNP) | VAF 120/479 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.369); called by muse, mutect2, varscan2
- OR4A47 | c.776C>T p.P259L | Missense Mutation (SNP) | VAF 93/367 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR4Q3 | c.293G>T p.G98V | Missense Mutation (SNP) | VAF 77/406 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- OR5K4 | c.473T>C p.I158T | Missense Mutation (SNP) | VAF 77/341 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- P4HB | c.1424_1429del p.Q475_G477delinsR | In Frame Del (DEL) | VAF 38/273 reads (14%) | called by mutect2, pindel, varscan2
- PCDHGA6 | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 75/361 reads (21%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PCDHGB4 | c.776C>T p.T259I | Missense Mutation (SNP) | VAF 73/425 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- PIGN | c.2441C>T p.S814F | Missense Mutation (SNP) | VAF 55/292 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PLA2R1 | c.3504del p.G1169Dfs*87 | Frame Shift Del (DEL) | VAF 64/317 reads (20%) | called by mutect2, pindel*, varscan2
- POF1B | c.975T>A p.D325E | Missense Mutation (SNP) | VAF 81/190 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PPFIBP2 | c.2485T>C p.F829L | Missense Mutation (SNP) | VAF 72/278 reads (26%) | SIFT tolerated (0.71); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- PPM1E | c.1549G>A p.D517N | Missense Mutation (SNP) | VAF 81/420 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- PPP1R26 | c.1726G>T p.G576C | Missense Mutation (SNP) | VAF 92/458 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- PREX2 | c.1532T>G p.V511G | Missense Mutation (SNP) | VAF 39/253 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- PSMB4 | c.495-8_496del p.X165_splice | Splice Site (DEL) | VAF 47/460 reads (10%) | called by mutect2, pindel, varscan2
- RAB3GAP2 | c.1907G>T p.C636F | Missense Mutation (SNP) | VAF 55/360 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- RABGAP1 | c.2257A>T p.I753L | Missense Mutation (SNP) | VAF 42/294 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- RANBP2 | c.7619C>T p.A2540V | Missense Mutation (SNP) | VAF 94/468 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- RASA4 | c.833A>G p.H278R | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0); called by mutect2, varscan2
- REC8 | c.1526G>A p.R509K | Missense Mutation (SNP) | VAF 74/386 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, varscan2
- RGPD3 | c.2279G>A p.G760E | Missense Mutation (SNP) | VAF 84/681 reads (12%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ROS1 | c.3425T>C p.V1142A | Missense Mutation (SNP) | VAF 54/322 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- RP1 | c.1099G>A p.A367T | Missense Mutation (SNP) | VAF 54/345 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- RPL17-C18orf32 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 15/254 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.347); called by muse, mutect2
- RSC1A1 | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 66/334 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- RSPH4A | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 87/414 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- RTN1 | c.913G>A p.D305N | Missense Mutation (SNP) | VAF 80/436 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SDC2 | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 71/385 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- SDC2 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 72/386 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SDK1 | c.4616T>A p.V1539D | Missense Mutation (SNP) | VAF 54/292 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.122); called by mutect2, varscan2
- SEMA4D | c.2081C>T p.A694V | Missense Mutation (SNP) | VAF 100/566 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- SGIP1 | c.2296G>A p.G766R | Missense Mutation (SNP) | VAF 40/173 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- SH3BP5L | c.650G>A p.R217K | Missense Mutation (SNP) | VAF 93/647 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SH3TC2 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 72/413 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- SIGLEC5 | c.1609G>A p.E537K | Missense Mutation (SNP) | VAF 51/313 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- SIPA1L3 | c.4304T>C p.F1435S | Missense Mutation (SNP) | VAF 91/497 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- SLC12A5 | c.1262C>T p.S421F (on ENST00000454036 / NM_001134771.2; = p.S398F on NM_020708.5) | Missense Mutation (SNP) | VAF 87/369 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- SLC18B1 | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 41/298 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SLC24A2 | c.985C>T p.Q329* | Nonsense Mutation (SNP) | VAF 62/325 reads (19%) | called by muse, mutect2, varscan2
- SLC25A23 | c.760C>T p.P254S | Missense Mutation (SNP) | VAF 59/365 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC2A14 | c.1193T>A p.V398E | Missense Mutation (SNP) | VAF 86/458 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- SLC6A5 | c.653C>T p.P218L | Missense Mutation (SNP) | VAF 72/316 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SNAI1 | c.499G>A p.G167S | Missense Mutation (SNP) | VAF 83/452 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SNRNP48 | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 63/290 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SNX9 | c.476C>G p.T159S | Missense Mutation (SNP) | VAF 56/270 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SPARC | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 71/340 reads (21%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); called by muse, varscan2
- SPATA31E1 | c.4042G>A p.D1348N | Missense Mutation (SNP) | VAF 86/497 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SRPX | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 100/240 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STAG3 | c.3040G>A p.E1014K | Missense Mutation (SNP) | VAF 176/396 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SYTL5 | c.1706-1G>A p.X569_splice | Splice Site (SNP) | VAF 41/114 reads (36%) | called by muse, mutect2, varscan2
- TAL1 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 64/318 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- TBC1D13 | c.860A>T p.K287M | Missense Mutation (SNP) | VAF 83/425 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- TCP11X2 | c.1348G>A p.G450R | Missense Mutation (SNP) | VAF 37/212 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- TDRD15 | c.2899G>A p.E967K | Missense Mutation (SNP) | VAF 29/207 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TET2 | c.3804G>A p.E1268= | Splice Region (SNP) | VAF 62/301 reads (21%) | called by muse, mutect2, varscan2
- TEX13C | c.590A>G p.E197G | Missense Mutation (SNP) | VAF 89/258 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- THBS4 | c.1226G>A p.G409E | Missense Mutation (SNP) | VAF 52/295 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- THSD7B | c.3964G>A p.G1322R (on ENST00000272643; = p.G1320R on NM_001316349.2) | Missense Mutation (SNP) | VAF 49/259 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TLE2 | c.1943G>A p.G648E | Missense Mutation (SNP) | VAF 70/365 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- TMEM59L | c.968C>T p.S323F | Missense Mutation (SNP) | VAF 77/382 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- TMTC1 | c.2141C>T p.P714L (on ENST00000539277 / NM_001193451.2; = p.P606L on NM_175861.3) | Missense Mutation (SNP) | VAF 71/374 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- TOPAZ1 | c.996A>T p.K332N | Missense Mutation (SNP) | VAF 71/400 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRPM6 | c.934C>T p.P312S | Missense Mutation (SNP) | VAF 83/439 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TSPEAR | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 61/200 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- TTC28 | c.109C>T p.L37F | Missense Mutation (SNP) | VAF 72/309 reads (23%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- UCN2 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 120/580 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- UNC79 | c.3470A>T p.D1157V (on ENST00000393151 / NM_001346218.2; = p.D980V on NM_020818.5) | Missense Mutation (SNP) | VAF 125/510 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- UNK | c.1159C>T p.P387S | Missense Mutation (SNP) | VAF 89/479 reads (19%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- UQCRC1 | c.427+1G>A p.X143_splice | Splice Site (SNP) | VAF 48/239 reads (20%) | called by muse, mutect2, varscan2
- VCAM1 | c.173C>T p.S58F | Missense Mutation (SNP) | VAF 58/251 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VPS72 | c.385+1G>C p.X129_splice | Splice Site (SNP) | VAF 170/378 reads (45%) | called by muse, mutect2, varscan2
- ZNF107 | c.1393G>A p.E465K | Missense Mutation (SNP) | VAF 72/512 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- ZNF354C | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 75/380 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- ZNF557 | c.1174A>T p.T392S (on ENST00000414706 / NM_001044388.2; = p.T399S on NM_024341.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/314 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ZNF722P | c.167G>T p.G56V | Missense Mutation (SNP) | VAF 36/259 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by mutect2, varscan2
- ZNF770 | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 66/334 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF845 | c.1873C>T p.H625Y | Missense Mutation (SNP) | VAF 85/421 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ABCA9 | c.4692A>G p.L1564= | Silent (SNP) | VAF 50/297 reads (17%) | catalogued as rs544367399; called by muse, mutect2, varscan2
- ABCC12 | c.135G>A p.P45= | Silent (SNP) | VAF 62/358 reads (17%) | catalogued as rs779621753, COSV60914164; called by muse, mutect2, varscan2
- ACBD7 | c.267G>A p.*89= | Silent (SNP) | VAF 41/191 reads (21%) | called by muse, mutect2, varscan2
- ADAM7 | c.669G>A p.R223= | Silent (SNP) | VAF 62/278 reads (22%) | called by muse, mutect2, varscan2
- ADCY1 | c.2109C>T p.P703= | Silent (SNP) | VAF 132/538 reads (25%) | called by muse, mutect2, varscan2
- ADCY5 | c.2748C>T p.L916= | Silent (SNP) | VAF 66/371 reads (18%) | catalogued as COSV59193966; called by muse, mutect2, varscan2
- ADGRB1 | c.4707G>A p.T1569= | Silent (SNP) | VAF 80/432 reads (19%) | catalogued as rs766809161; called by muse, mutect2, varscan2
- ADGRB2 | c.4494C>T p.Y1498= (on ENST00000373658 / NM_001364857.2; = p.Y1497= on NM_001294335.2) | Silent (SNP) | VAF 65/366 reads (18%) | called by muse, mutect2, varscan2
- AIP | c.159C>T p.S53= | Silent (SNP) | VAF 119/402 reads (30%) | catalogued as rs764878127; ClinVar: likely benign; called by muse, mutect2, varscan2
- ANKRD1 | c.765G>A p.P255= | Silent (SNP) | VAF 26/203 reads (13%) | catalogued as COSV100865327; called by muse, mutect2, varscan2
- AP1B1 | c.303C>T p.L101= | Silent (SNP) | VAF 71/323 reads (22%) | catalogued as COSV58016367; called by muse, mutect2, varscan2
- APOL1 | c.258C>T p.L86= | Silent (SNP) | VAF 49/308 reads (16%) | called by muse, mutect2, varscan2
- ARHGAP44 | c.804C>T p.I268= | Silent (SNP) | VAF 95/449 reads (21%) | catalogued as rs766941988, COSV52391992; called by muse, varscan2
- ARHGEF35 | c.1230G>A p.L410= | Silent (SNP) | VAF 76/722 reads (11%) | called by muse, mutect2, varscan2
- ATP10D | c.3010C>T p.L1004= | Silent (SNP) | VAF 98/437 reads (22%) | called by muse, mutect2, varscan2
- BIRC5 | c.33G>A p.Q11= | Silent (SNP) | VAF 88/421 reads (21%) | called by muse, mutect2, varscan2
- C20orf194 | c.1857C>T p.F619= | Silent (SNP) | VAF 76/384 reads (20%) | called by muse, mutect2, varscan2
- C5 | c.3174C>T p.S1058= | Silent (SNP) | VAF 70/369 reads (19%) | called by muse, mutect2, varscan2
- CAND2 | c.1203C>T p.I401= (on ENST00000456430 / NM_001162499.2; = p.I308= on NM_012298.3) | Silent (SNP) | VAF 74/497 reads (15%) | catalogued as rs757999829, COSV55986943; called by muse, mutect2, varscan2
- CBLN1 | c.414G>A p.V138= | Silent (SNP) | VAF 81/390 reads (21%) | called by muse, mutect2, varscan2
- CD96 | c.159C>T p.F53= | Silent (SNP) | VAF 120/488 reads (25%) | catalogued as rs140137237; called by muse, mutect2, varscan2
- CDH17 | c.1263G>A p.T421= | Silent (SNP) | VAF 53/279 reads (19%) | catalogued as rs377170293; called by muse, mutect2, varscan2
- CDYL2 | c.1137C>T p.F379= | Silent (SNP) | VAF 91/550 reads (17%) | called by muse, mutect2, varscan2
- CEACAM18 | c.822G>A p.L274= | Silent (SNP) | VAF 80/400 reads (20%) | called by muse, mutect2, varscan2
- CFAP54 | c.6372G>A p.L2124= | Silent (SNP) | VAF 31/190 reads (16%) | catalogued as rs1195188811; called by muse, mutect2, varscan2
- CHRM3 | c.1101C>T p.I367= | Silent (SNP) | VAF 217/532 reads (41%) | catalogued as rs199545608, COSV55085308; called by muse, mutect2, varscan2
- CNOT7 | c.441C>T p.L147= | Silent (SNP) | VAF 91/362 reads (25%) | called by muse, mutect2, varscan2
- CNPY2 | c.246G>T p.L82= | Silent (SNP) | VAF 76/386 reads (20%) | called by muse, mutect2, varscan2
- COL6A1 | c.3012C>T p.F1004= | Silent (SNP) | VAF 104/422 reads (25%) | catalogued as COSV62615789; called by muse, mutect2, varscan2
- CPNE5 | c.1005C>T p.F335= | Silent (SNP) | VAF 110/476 reads (23%) | called by muse, mutect2, varscan2
- CUX2 | c.3120C>T p.I1040= | Silent (SNP) | VAF 91/535 reads (17%) | catalogued as rs1405869296, COSV55629406; called by muse, mutect2, varscan2
- DDX31 | c.216G>A p.R72= | Silent (SNP) | VAF 128/575 reads (22%) | catalogued as rs1381199945, COSV100140386; called by muse, mutect2, varscan2
- DNAH5 | c.8763C>T p.I2921= | Silent (SNP) | VAF 128/469 reads (27%) | called by muse, mutect2, varscan2
- DNAH6 | c.9090C>T p.I3030= | Silent (SNP) | VAF 67/325 reads (21%) | catalogued as rs1016695519; called by muse, mutect2, varscan2
- DSE | c.1608C>T p.F536= | Silent (SNP) | VAF 82/468 reads (18%) | catalogued as rs764179730, COSV59064133; called by muse, mutect2, varscan2
- ENPEP | c.48G>A p.T16= | Silent (SNP) | VAF 82/390 reads (21%) | catalogued as rs1225718514, COSV54454125; called by muse, mutect2, varscan2
- EPB41L4B | c.2544C>T p.I848= | Silent (SNP) | VAF 74/428 reads (17%) | called by muse, mutect2, varscan2
- EPHB2 | c.165G>A p.T55= | Silent (SNP) | VAF 75/364 reads (21%) | catalogued as rs201427890; called by muse, mutect2, varscan2
- FGFR4 | c.1014C>T p.S338= | Silent (SNP) | VAF 81/425 reads (19%) | catalogued as rs867798832; called by muse, mutect2, varscan2
- FILIP1 | c.3357G>A p.R1119= | Silent (SNP) | VAF 81/392 reads (21%) | called by muse, mutect2, varscan2
- FRMPD1 | c.1743G>A p.T581= | Silent (SNP) | VAF 108/502 reads (22%) | catalogued as rs369271811; called by muse, mutect2, varscan2
- FRY | c.3723C>T p.A1241= | Silent (SNP) | VAF 23/315 reads (7%) | called by muse, mutect2
- FSIP2 | c.18039G>A p.L6013= | Silent (SNP) | VAF 80/387 reads (21%) | called by muse, mutect2, varscan2
- GBP1 | c.1362G>A p.G454= | Silent (SNP) | VAF 47/205 reads (23%) | catalogued as rs928093455; called by muse, mutect2, varscan2
- GBP7 | c.603G>A p.E201= | Silent (SNP) | VAF 54/223 reads (24%) | called by muse, mutect2, varscan2
- GREB1L | c.3906G>A p.L1302= | Silent (SNP) | VAF 85/411 reads (21%) | called by muse, mutect2, varscan2
- H3C4 | c.282G>A p.Q94= | Silent (SNP) | VAF 71/403 reads (18%) | catalogued as COSV61912003; called by muse, mutect2, varscan2
- HCK | c.111C>T p.F37= | Silent (SNP) | VAF 80/378 reads (21%) | called by muse, mutect2, varscan2
- HID1 | c.1536C>T p.A512= | Silent (SNP) | VAF 78/430 reads (18%) | called by muse, mutect2, varscan2
- HYDIN | c.13800G>A p.K4600= | Silent (SNP) | VAF 67/346 reads (19%) | called by muse, mutect2, varscan2
- IGF2BP1 | c.1728G>A p.R576= | Silent (SNP) | VAF 51/267 reads (19%) | catalogued as rs997617031, COSV51734635; called by muse, mutect2, varscan2
- IGHG1 | c.276C>T p.T92= | Silent (SNP) | VAF 61/312 reads (20%) | catalogued as rs758399075; called by muse, mutect2, varscan2
- IGHV3-20 | c.138C>T p.F46= | Silent (SNP) | VAF 68/296 reads (23%) | called by muse, mutect2, varscan2
- IGLV3-16 | c.319C>T p.L107= | Silent (SNP) | VAF 46/236 reads (19%) | called by muse, mutect2, varscan2
- IL10RA | c.792G>A p.K264= | Silent (SNP) | VAF 110/332 reads (33%) | called by muse, mutect2, varscan2
- IL1RAPL2 | c.1542G>A p.G514= | Silent (SNP) | VAF 104/257 reads (40%) | called by muse, mutect2, varscan2
- INPP5E | c.1023C>T p.G341= | Silent (SNP) | VAF 64/369 reads (17%) | called by muse, mutect2, varscan2
- INSRR | c.171C>T p.I57= | Silent (SNP) | VAF 112/731 reads (15%) | called by muse, mutect2, varscan2
- ITGA11 | c.297G>A p.R99= | Silent (SNP) | VAF 44/309 reads (14%) | catalogued as COSV59881968; called by muse, mutect2, varscan2
- JAKMIP1 | c.6G>A p.S2= | Silent (SNP) | VAF 65/305 reads (21%) | catalogued as rs774024893, COSV51547595; called by muse, mutect2, varscan2
- JDP2 | c.483G>A p.E161= | Silent (SNP) | VAF 66/307 reads (21%) | called by muse, mutect2, varscan2
- KCNG2 | c.537C>T p.F179= | Silent (SNP) | VAF 85/422 reads (20%) | catalogued as rs765638471, COSV60267089; called by muse, mutect2, varscan2
- KCNT2 | c.906C>T p.V302= | Silent (SNP) | VAF 210/525 reads (40%) | catalogued as rs372036906, COSV54107097; called by muse, mutect2, varscan2
- KCNV1 | c.555C>T p.S185= | Silent (SNP) | VAF 95/480 reads (20%) | catalogued as COSV52089557; called by muse, mutect2, varscan2
- KDM4C | c.1632C>T p.I544= | Silent (SNP) | VAF 83/406 reads (20%) | catalogued as COSV101185086; called by muse, mutect2, varscan2
- KIF26B | c.1005C>T p.S335= | Silent (SNP) | VAF 52/413 reads (13%) | called by muse, mutect2, varscan2
- KRT6A | c.1218G>A p.Q406= | Silent (SNP) | VAF 80/362 reads (22%) | called by muse, mutect2, varscan2
- LMOD2 | c.693C>T p.R231= | Silent (SNP) | VAF 271/652 reads (42%) | called by muse, mutect2, varscan2
- LRRN3 | c.1059C>T p.T353= | Silent (SNP) | VAF 286/657 reads (44%) | called by muse, mutect2, varscan2
- LTBP4 | c.1875G>T p.A625= (on ENST00000308370 / NM_001042544.1; = p.A588= on NM_003573.2) | Silent (SNP) | VAF 72/317 reads (23%) | called by muse, mutect2, varscan2
- MAEL | c.141G>A p.R47= | Silent (SNP) | VAF 48/402 reads (12%) | called by muse, mutect2, varscan2
- MAGEC1 | c.2250C>T p.S750= | Silent (SNP) | VAF 106/321 reads (33%) | called by muse, mutect2, varscan2
- MAP3K13 | c.2301G>A p.L767= | Silent (SNP) | VAF 69/407 reads (17%) | catalogued as rs143261551; called by muse, mutect2, varscan2
- MDGA2 | c.2637C>G p.G879= (on ENST00000399232 / NM_001113498.2; = p.G581= on NM_182830.4) | Silent (SNP) | VAF 75/398 reads (19%) | called by muse, mutect2, varscan2
- MGAM2 | c.4953G>A p.R1651= | Silent (SNP) | VAF 137/447 reads (31%) | called by muse, mutect2, varscan2
- MMP13 | c.222C>T p.F74= | Silent (SNP) | VAF 71/335 reads (21%) | called by muse, mutect2, varscan2
- MORC1 | c.81C>T p.F27= | Silent (SNP) | VAF 51/345 reads (15%) | catalogued as COSV51712973; called by muse, mutect2, varscan2
- MXRA5 | c.8415C>T p.A2805= | Silent (SNP) | VAF 96/270 reads (36%) | catalogued as rs1290233773, COSV54240258; called by muse, mutect2, varscan2
- MYBPC1 | c.1857C>T p.F619= (on ENST00000550270 / NM_206820.2; = p.F644= on NM_002465.4) | Silent (SNP) | VAF 52/273 reads (19%) | catalogued as rs754810728; called by muse, mutect2, varscan2
- MYBPC1 | c.3159G>A p.L1053= (on ENST00000550270 / NM_206820.2; = p.L1060= on NM_002465.4) | Silent (SNP) | VAF 86/506 reads (17%) | called by muse, mutect2, varscan2
- MYLK3 | c.2019C>T p.F673= | Silent (SNP) | VAF 65/230 reads (28%) | catalogued as rs373988254; called by muse, mutect2, varscan2
- MYO18B | c.2298G>A p.L766= | Silent (SNP) | VAF 59/286 reads (21%) | called by muse, mutect2, varscan2
- MYO1A | c.2247G>A p.L749= | Silent (SNP) | VAF 74/388 reads (19%) | catalogued as rs1279480015; called by muse, mutect2, varscan2
- MYOC | c.1080C>T p.I360= | Silent (SNP) | VAF 88/680 reads (13%) | called by muse, mutect2, varscan2
- NALCN | c.4665G>A p.A1555= | Silent (SNP) | VAF 77/333 reads (23%) | catalogued as rs745411043; called by muse, mutect2, varscan2
- NCAPD3 | c.3225C>T p.F1075= | Silent (SNP) | VAF 41/179 reads (23%) | catalogued as rs745318981; called by muse, mutect2, varscan2
- NOD2 | c.1998C>T p.A666= | Silent (SNP) | VAF 110/575 reads (19%) | catalogued as rs374171106; called by muse, varscan2
- NOP2 | c.1557C>T p.I519= (on ENST00000322166 / NM_001258308.2; = p.I515= on NM_006170.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 48/248 reads (19%) | called by muse, mutect2, varscan2
- NOTCH1 | c.4440C>T p.S1480= | Silent (SNP) | VAF 115/521 reads (22%) | catalogued as rs1316866002; called by muse, mutect2, varscan2
- NPIPA5 | c.444G>A p.R148= | Silent (SNP) | VAF 28/256 reads (11%) | called by muse, mutect2, varscan2
- OR13C5 | c.150C>T p.I50= | Silent (SNP) | VAF 46/342 reads (13%) | called by muse, mutect2, varscan2
- OR2W3 | c.630C>T p.P210= | Silent (SNP) | VAF 65/550 reads (12%) | catalogued as rs759183657; called by muse, mutect2, varscan2
- OR8J3 | c.426C>T p.L142= | Silent (SNP) | VAF 109/380 reads (29%) | catalogued as rs770591214, COSV56880973; called by muse, mutect2, varscan2
- ORAI3 | c.111C>T p.D37= | Silent (SNP) | VAF 86/453 reads (19%) | catalogued as rs764027314; called by muse, mutect2, varscan2
- OTOP2 | c.795G>A p.V265= | Silent (SNP) | VAF 94/493 reads (19%) | called by muse, mutect2, varscan2
- P2RX1 | c.537C>T p.L179= | Silent (SNP) | VAF 55/293 reads (19%) | catalogued as COSV56653395; called by muse, mutect2, varscan2
- PACRG | c.267G>A p.S89= | Silent (SNP) | VAF 59/299 reads (20%) | catalogued as rs759185651, COSV61305720; called by muse, mutect2, varscan2
- PATJ | c.2307C>T p.I769= | Silent (SNP) | VAF 58/321 reads (18%) | catalogued as rs931642158; called by muse, mutect2, varscan2
- PAX7 | c.843G>A p.L281= | Silent (SNP) | VAF 117/534 reads (22%) | catalogued as rs1460863351; called by muse, mutect2, varscan2
- PCDHB4 | c.924C>T p.F308= | Silent (SNP) | VAF 44/326 reads (13%) | catalogued as COSV52021508; called by muse, mutect2, varscan2
- PDE1A | c.1584G>A p.Q528= | Silent (SNP) | VAF 72/380 reads (19%) | called by muse, mutect2
- PHLDB2 | c.3432G>A p.K1144= (on ENST00000393925 / NM_001134439.2; = p.K1101= on NM_145753.2) | Silent (SNP) | VAF 82/455 reads (18%) | called by muse, mutect2, varscan2
- PLCB1 | c.918C>T p.V306= | Silent (SNP) | VAF 89/405 reads (22%) | catalogued as COSV62054522; called by muse, mutect2, varscan2
- PLOD1 | c.1521C>T p.S507= | Silent (SNP) | VAF 68/378 reads (18%) | called by muse, mutect2, varscan2
- PNPLA1 | c.718C>T p.L240= (on ENST00000394571 / NM_001374623.1; = p.L145= on NM_173676.2) | Silent (SNP) | VAF 65/348 reads (19%) | called by muse, mutect2, varscan2
- PPIP5K2 | c.2169C>T p.I723= | Silent (SNP) | VAF 51/307 reads (17%) | called by muse, mutect2, varscan2
- PRSS16 | c.648G>A p.L216= | Silent (SNP) | VAF 94/411 reads (23%) | called by muse, mutect2, varscan2
- RAB3A | c.120C>T p.F40= | Silent (SNP) | VAF 67/371 reads (18%) | catalogued as rs773206072; called by muse, mutect2, varscan2
- RALGAPA2 | c.4740C>T p.F1580= | Silent (SNP) | VAF 88/525 reads (17%) | catalogued as rs780044972, COSV52491071; called by muse, mutect2, varscan2
- RASD2 | c.507C>T p.F169= | Silent (SNP) | VAF 100/503 reads (20%) | catalogued as rs773156408, COSV53352277; called by muse, mutect2, varscan2
- RBMS2 | c.867G>A p.S289= | Silent (SNP) | VAF 63/326 reads (19%) | catalogued as rs61617845; called by muse, mutect2, varscan2
- RPN1 | c.882G>A p.R294= | Silent (SNP) | VAF 61/343 reads (18%) | called by muse, mutect2, varscan2
- SDS | c.951G>A p.K317= | Silent (SNP) | VAF 91/369 reads (25%) | called by muse, mutect2, varscan2
- SECISBP2 | c.1959C>T p.V653= | Silent (SNP) | VAF 99/449 reads (22%) | called by muse, mutect2, varscan2
- SEMA3D | c.1590C>T p.S530= | Silent (SNP) | VAF 70/361 reads (19%) | catalogued as COSV52390046; called by muse, mutect2, varscan2
- SLC11A2 | c.810C>T p.F270= (on ENST00000394904 / NM_001379455.1; = p.F241= on NM_000617.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 77/453 reads (17%) | catalogued as rs749882321, COSV50374405; called by muse, mutect2, varscan2
- SLC12A1 | c.657C>T p.S219= | Silent (SNP) | VAF 73/401 reads (18%) | catalogued as rs1467459145; called by muse, mutect2, varscan2
- SLC12A3 | c.2169C>T p.I723= | Silent (SNP) | VAF 59/266 reads (22%) | called by muse, mutect2, varscan2
- SLC25A23 | c.759C>T p.A253= | Silent (SNP) | VAF 61/369 reads (17%) | called by muse, mutect2, varscan2
- SLC27A1 | c.402C>T p.F134= | Silent (SNP) | VAF 105/547 reads (19%) | called by muse, mutect2, varscan2
- SLC2A13 | c.1125C>T p.F375= | Silent (SNP) | VAF 90/429 reads (21%) | catalogued as rs773186400, COSV99786192, COSV99786195; called by muse, mutect2, varscan2
- SLC35A4 | c.204C>T p.S68= | Silent (SNP) | VAF 111/562 reads (20%) | catalogued as COSV60051695; called by muse, mutect2, varscan2
- SLC35G3 | c.930C>T p.I310= | Silent (SNP) | VAF 129/603 reads (21%) | catalogued as rs866561974; called by muse, mutect2, varscan2
- SPO11 | c.54A>G p.R18= | Silent (SNP) | VAF 64/402 reads (16%) | called by muse, mutect2, varscan2
- SPTBN5 | c.919C>T p.L307= | Silent (SNP) | VAF 46/348 reads (13%) | called by muse, mutect2, varscan2
- ST18 | c.2943G>A p.E981= | Silent (SNP) | VAF 85/447 reads (19%) | catalogued as COSV99388793; called by muse, mutect2, varscan2
- STMN4 | c.70C>T p.L24= | Silent (SNP) | VAF 67/359 reads (19%) | called by muse, mutect2, varscan2
- STXBP1 | c.1524C>T p.A508= | Silent (SNP) | VAF 74/377 reads (20%) | called by muse, mutect2, varscan2
- TAF11L2 | c.417G>A p.A139= | Silent (SNP) | VAF 199/584 reads (34%) | catalogued as rs532057099; called by muse, mutect2, varscan2
- TAOK1 | c.951C>T p.F317= | Silent (SNP) | VAF 69/419 reads (16%) | catalogued as COSV55594774; called by muse, mutect2, varscan2
- THUMPD3 | c.387C>T p.P129= | Silent (SNP) | VAF 48/248 reads (19%) | called by muse, mutect2, varscan2
- TLR5 | c.1605C>T p.S535= | Silent (SNP) | VAF 67/645 reads (10%) | called by muse, mutect2, varscan2
- TMX4 | c.135C>T p.S45= | Silent (SNP) | VAF 62/382 reads (16%) | called by muse, mutect2, varscan2
- TRPS1 | c.1980C>T p.V660= (on ENST00000220888 / NM_001330599.2; = p.V673= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 116/476 reads (24%) | catalogued as rs999007445, COSV55249451; called by muse, mutect2, varscan2
- TTC39B | c.879C>T p.F293= | Silent (SNP) | VAF 59/295 reads (20%) | called by muse, mutect2, varscan2
- TUBD1 | c.597C>T p.D199= | Silent (SNP) | VAF 84/411 reads (20%) | catalogued as rs774138544; called by muse, mutect2, varscan2
- UCK2 | c.399C>T p.L133= | Silent (SNP) | VAF 70/540 reads (13%) | called by muse, mutect2, varscan2
- ZFAND2A | c.384C>T p.H128= | Silent (SNP) | VAF 86/382 reads (23%) | called by muse, mutect2, varscan2
- ZNF142 | c.2872C>T p.L958= (on ENST00000411696 / NM_001379660.1; = p.L758= on NM_001105537.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 86/431 reads (20%) | catalogued as rs758556928; called by muse, mutect2, varscan2
- ZNF334 | c.906C>T p.F302= | Silent (SNP) | VAF 84/436 reads (19%) | called by muse, mutect2, varscan2
- ZNF558 | c.325C>T p.L109= | Silent (SNP) | VAF 49/261 reads (19%) | catalogued as COSV56863374; called by muse, mutect2, varscan2
- ZXDC | c.1938C>T p.P646= | Silent (SNP) | VAF 80/452 reads (18%) | called by mutect2, varscan2
- ZYG11B | c.1413C>T p.I471= | Silent (SNP) | VAF 49/286 reads (17%) | called by muse, mutect2, varscan2
- AC016747.1 | n.295C>T | RNA (SNP) | VAF 69/367 reads (19%) | called by muse, mutect2, varscan2
- AC098487.1 | n.384C>T | RNA (SNP) | VAF 79/377 reads (21%) | called by muse, mutect2, varscan2
- AFP | c.*47G>A | 3'UTR (SNP) | VAF 36/269 reads (13%) | called by muse, mutect2, varscan2
- CBR1 | c.398-139C>T | Intron (SNP) | VAF 81/357 reads (23%) | catalogued as rs762177714; called by muse, mutect2, varscan2
- CPLANE1 | c.*5024C>T | 3'UTR (SNP) | VAF 69/404 reads (17%) | called by muse, mutect2, varscan2
- CXCL12 | c.266+2606G>A | Intron (SNP) | VAF 40/140 reads (29%) | catalogued as rs200785547; called by muse, mutect2, varscan2
- DYRK4 | chr12:4588989 A>G | 5'Flank (SNP) | VAF 79/346 reads (23%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1393+31064G>A | Intron (SNP) | VAF 58/263 reads (22%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1394-6211G>A | Intron (SNP) | VAF 33/203 reads (16%) | catalogued as rs144375995; called by muse, mutect2, varscan2
- MLIP | c.613-11336C>T | Intron (SNP) | VAF 100/446 reads (22%) | called by muse, varscan2
- MLIP | c.613-11289G>A | Intron (SNP) | VAF 94/478 reads (20%) | called by muse, varscan2
- NSUN4 | c.94-1452C>T | Intron (SNP) | VAF 76/368 reads (21%) | called by muse, mutect2
- SH2D3C | c.515+2767G>T | Intron (SNP) | VAF 94/428 reads (22%) | called by muse, mutect2, varscan2
- SLC12A8 | c.737-97C>T | Intron (SNP) | VAF 95/517 reads (18%) | called by muse, mutect2, varscan2
- SPEF2 | c.5379+456A>G | Intron (SNP) | VAF 138/418 reads (33%) | called by muse, mutect2, varscan2
- TTN | c.34265-5693C>T | Intron (SNP) | VAF 77/363 reads (21%) | catalogued as rs1384922524, COSV59890302; called by muse, mutect2, varscan2
- TTN | c.34264+584C>T | Intron (SNP) | VAF 56/290 reads (19%) | catalogued as rs375507473, COSV60180893; called by muse, mutect2, varscan2
- TTN | c.10361-4045G>A | Intron (SNP) | VAF 90/375 reads (24%) | called by muse, mutect2, varscan2
